Surgical pathology report (de-identified scan), TCGA case TCGA-VM-A8CE, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Huntsman Cancer Institute, specimen TCGA-VM-A8CE-01A (Primary Tumor).

[page 1 of 4]
SurgPath Final Report

Temporary Copy

Case #

Collected

Ordered by

Page 1 of 2

Patient

ID

Location

ACCESSION

Submitting Physician

Clinical History

L brain tumor

Diagnosis

1. "BRAIN TUMOR", (BIOPSY):

- OLIGODENDROGLIOMA, GRADE 2.
- PLEASE SEE COMMENT.

2. "BRAIN TUMOR - GLIOMA", (PROCEDURE NOT SPECIFIED):

- OLIGODENDROGLIOMA, GRADE 2.
- PLEASE SEE COMMENT.
- PLEASE SEE SYNOPTIC REPORT.

I certify that I personally conducted the diagnostic evaluation on the above specimens and have rendered the above diagnosis(es):

electronic signature

For questions regarding this case, call

Comments

This case will be sent in consultation to conformation of this diagnosis.

Frozen Section Diagnosis

Frozen section diagnosis per

1FA: "Glioma present."

Gross Description

Two containers are received labeled with patient name and medical record number.

Specimen one is received fresh for frozen section labeled "brain tumor - glioma". The specimen consists of a 2.5 x 1.8 x 1.1 cm piece of white matter. Half of this tissue is taken for frozen section. Specimen is submitted in total in block 1FA frozen section control and cassette 1A remainder of tissue.

Specimen two is received in formalin labeled "brain tumor - glioma". The specimen consists of a 3.5 x 3.5 x 1.5 cm portion of pink-grey matter. Serial sectioning shows a uniform white to pink cut surface. No discrete nodules are identified. Representative sections submitted in cassette 2A-2C.

ICD-O-3
Oligodendroglioma, grade II
945013
Site ^{CBE} Brain, supratentorial
Cerebrum
C71.0
Jr 11/27/13

[page 2 of 4]
Specimen
Collected
Ordered by

Patient
ID
Location

Microscopic Examination

Performed.

Synoptic Report

No AJCC/UICC TNM Staging System

Protocol web posting date:

Protocol effective date:

*History of previous tumor/familial syndrome: None known

Specimen type/procedure: Open biopsy

Specimen handling: Frozen tissue

Unfrozen for permanent paraffin sections

*Specimen size: Greatest dimension: 3.5 cm

Laterality: Not specified

Tumor site: Brain, cerebrum

Histologic type and grade: Oligodendroglial tumors

Histologic Grade: Oligodendroglioma grade 2

Margins: Cannot be assessed

*Ancillary studies: To be performed

[page 3 of 4]
Addendum Report

Temporary Copy

Page 1 of 1

Case

Collected

Ordered by

Patient

is

Location

ACCESSION

Addendum Discussion

This case was sent in consultation to
diagnosis is as follows:

at

"BRAIN TUMOR, SITE NOT SPECIFIED", (RESECTION):

- OLIGODENDROGLIOMA, WHO GRADE II

DIAGNOSIS REMAINS UNCHANGED.

I certify that I personally conducted the
diagnostic evaluation on the above specimen(s)
and have rendered the above diagnosis(es):

electronic signature

[page 4 of 4]
Addendum Report

Temporary Copy

Page 1 of 1

Case

Collected

Ordered by

ACCESSION

Addendum Discussion

1p/19q FISH

Fluorescence in-situ hybridization (FISH) analysis for deletions of chromosomes 1p and 19q are performed on sections from block "2A".

Calculated 1p/1q ratio = 0.57 (<0.74 is deleted)
Calculated 19q/19p ratio = 0.55 (<0.88 is deleted)

The results are interpreted as deleted for 1p and 19q. This assay was read by

A result of a deleted 1p and 19q suggests a favorable prognosis.

I certify that I personally conducted the
diagnostic evaluation on the above specimen(s)
and have rendered the above diagnosis(es):

electronic signature

Source: NCI Genomic Data Commons file bc404233-f77a-4245-a167-2804e7f4abc2 (TCGA-VM-A8CE.E89B7ED7-D8CA-4112-B0D9-0B2A72941DC8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).